Somatic mutation profile of tumor specimen C3N-01179-01 (aliquot CPT0088900009) from CPTAC case C3N-01179, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 72.5 years (26,483 days).
Specimen C3N-01179-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dea3fcc5-a675-44ae-a1bb-be492dcf485b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01179-31 (Blood Derived Normal), aliquot CPT0088960002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d11a43e5-4837-4f97-b495-4051322a3d81

The open-access MAF lists 87 somatic variants for this specimen: 58 protein-altering or splice-affecting, 22 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 37, Silent 22, Frame Shift Del 9, Nonsense Mutation 4, Intron 4, Splice Site 2, Splice Region 2, 3'UTR 2, Frame Shift Ins 2, In Frame Ins 1, 5'UTR 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.340+1G>A p.X114_splice | Splice Site (SNP) | VAF 62/233 reads (27%) | hotspot (GDC flag); catalogued as rs730882032, CS044968, CS982396, COSV56543763, COSV56544858, COSV56545042, COSV56546938; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AIF1 | c.299C>T p.T100M | Missense Mutation (SNP) | VAF 26/106 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); catalogued as rs759958730; called by muse, mutect2, varscan2
- BIRC2 | c.1762C>T p.H588Y | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57162832; called by muse, mutect2, varscan2
- EEF1A1 | c.1228A>G p.M410V | Missense Mutation (SNP) | VAF 28/193 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.012); catalogued as rs755529377; called by muse, mutect2, varscan2
- NCCRP1 | c.778C>T p.R260W | Missense Mutation (SNP) | VAF 34/201 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.019); catalogued as rs772826705, COSV59212405; called by muse, mutect2, varscan2
- NID2 | c.2834G>T p.R945L | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as COSV53493966; called by muse, varscan2
- PTPRK | c.3869G>A p.G1290E (on ENST00000368215 / NM_001291984.2; = p.G1291E on NM_002844.4) | Missense Mutation (SNP) | VAF 42/202 reads (21%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.958); catalogued as COSV63903985; called by muse, mutect2, varscan2
- ROBO3 | c.250C>T p.P84S | Missense Mutation (SNP) | VAF 51/211 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.262); catalogued as rs1440060658; called by muse, mutect2, varscan2
- SAMD14 | c.115G>T p.A39S | Missense Mutation (SNP) | VAF 44/214 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.528); catalogued as COSV53311324; called by muse, mutect2, varscan2
- TOGARAM1 | c.1933T>A p.C645S | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT tolerated (0.48); PolyPhen benign (0.02); catalogued as COSV61887580; called by muse, mutect2, varscan2
- TTLL10 | c.1834C>A p.P612T | Missense Mutation (SNP) | VAF 45/165 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.017); catalogued as rs1279388774; called by muse, mutect2, varscan2
- ZGPAT | c.118C>T p.Q40* | Nonsense Mutation (SNP) | VAF 53/198 reads (27%) | catalogued as COSV100157448; called by muse, mutect2, varscan2
- ABCD4 | c.1055T>A p.L352Q | Missense Mutation (SNP) | VAF 57/267 reads (21%) | SIFT tolerated (0.62); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ACAN | c.625_626del p.V209Qfs*17 | Frame Shift Del (DEL) | VAF 10/53 reads (19%) | called by mutect2, pindel, varscan2
- ADGRB3 | c.1662_1669del p.G555Lfs*14 | Frame Shift Del (DEL) | VAF 25/155 reads (16%) | called by mutect2, pindel, varscan2
- AHNAK | c.2314A>G p.N772D | Missense Mutation (SNP) | VAF 107/506 reads (21%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ARFGEF2 | c.4798C>T p.Q1600* | Nonsense Mutation (SNP) | VAF 133/526 reads (25%) | called by muse, mutect2, varscan2
- BTF3L4 | c.52A>C p.K18Q | Missense Mutation (SNP) | VAF 9/154 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); called by muse, mutect2
- CCDC168 | c.483C>G p.I161M | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.633); called by muse, mutect2, varscan2
- CEACAM7 | c.595A>G p.R199G | Missense Mutation (SNP) | VAF 86/397 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- CHD6 | c.2425G>A p.V809M | Missense Mutation (SNP) | VAF 44/166 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DICER1 | c.3460A>G p.R1154G | Missense Mutation (SNP) | VAF 44/183 reads (24%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- ECEL1 | c.2070G>T p.W690C | Missense Mutation (SNP) | VAF 41/168 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- EPHX3 | c.803T>G p.F268C | Missense Mutation (SNP) | VAF 46/211 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.622); called by muse, mutect2, varscan2
- GSTO1 | c.10del p.E4Sfs*26 | Frame Shift Del (DEL) | VAF 41/232 reads (18%) | called by mutect2, pindel, varscan2
- HIPK2 | c.3137A>T p.H1046L | Missense Mutation (SNP) | VAF 42/178 reads (24%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- IGDCC4 | c.521T>C p.I174T | Missense Mutation (SNP) | VAF 46/222 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- IL18BP | c.567_573del p.P190Sfs*27 | Frame Shift Del (DEL) | VAF 27/197 reads (14%) | called by mutect2, pindel
- IL21 | c.116T>G p.M39R | Missense Mutation (SNP) | VAF 57/220 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.718); called by muse, mutect2, varscan2
- INPP5B | c.87C>G p.D29E | Missense Mutation (SNP) | VAF 25/107 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- LCN9 | c.126_133del p.M42Ifs*2 | Frame Shift Del (DEL) | VAF 43/205 reads (21%) | called by mutect2, pindel, varscan2
- MINPP1 | c.1331C>G p.P444R | Missense Mutation (SNP) | VAF 50/159 reads (31%) | SIFT tolerated (0.29); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- NADSYN1 | c.798+3A>T | Splice Region (SNP) | VAF 82/401 reads (20%) | called by muse, varscan2
- NBEA | c.4677A>T p.Q1559H | Missense Mutation (SNP) | VAF 24/124 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- NDUFB4 | c.180+6T>A | Splice Region (SNP) | VAF 45/155 reads (29%) | called by muse, mutect2, varscan2
- NR2F1 | c.827_839del p.L276Sfs*77 | Frame Shift Del (DEL) | VAF 66/284 reads (23%) | called by mutect2, pindel, varscan2
- OR14A2 | c.875A>G p.N292S | Missense Mutation (SNP) | VAF 35/139 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.837); called by muse, varscan2
- OR6M1 | c.339G>C p.L113F | Missense Mutation (SNP) | VAF 36/160 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.606); called by muse, mutect2, varscan2
- PADI6 | c.573G>T p.Q191H | Missense Mutation (SNP) | VAF 81/294 reads (28%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.881); called by muse, mutect2, varscan2
- PBRM1 | c.3441C>G p.Y1147* (on ENST00000296302 / NM_001366071.2; = p.Y1122* on NM_018313.5) | Nonsense Mutation (SNP) | VAF 83/298 reads (28%) | called by muse, mutect2, varscan2
- PRPF39 | c.1013_1017delinsG p.I338Rfs*7 | Frame Shift Del (DEL) | VAF 10/29 reads (34%) | called by pindel, varscan2*
- RAD54L | c.674A>C p.N225T | Missense Mutation (SNP) | VAF 91/387 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- REL | c.1087+3_1087+10del p.X363_splice | Splice Site (DEL) | VAF 15/71 reads (21%) | called by mutect2, pindel
- SCYL2 | c.198del p.F66Lfs*5 | Frame Shift Del (DEL) | VAF 26/120 reads (22%) | called by mutect2, pindel
- SF3B1 | c.2581_2586dup p.A861_E862dup | In Frame Ins (INS) | VAF 20/113 reads (18%) | called by mutect2, varscan2
- SFXN4 | c.129del p.L44Ffs*7 | Frame Shift Del (DEL) | VAF 27/96 reads (28%) | called by mutect2, pindel, varscan2
- SLC46A2 | c.551G>T p.G184V | Missense Mutation (SNP) | VAF 40/163 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- STON1 | c.1149C>G p.Y383* | Nonsense Mutation (SNP) | VAF 44/186 reads (24%) | called by muse, mutect2, varscan2
- SYT1 | c.715G>C p.D239H | Missense Mutation (SNP) | VAF 42/186 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- TCTN3 | c.1460dup p.N487Kfs*127 | Frame Shift Ins (INS) | VAF 21/144 reads (15%) | called by mutect2, pindel, varscan2
- TNNC2 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 34/223 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- UBXN4 | c.1157C>T p.A386V | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.655); called by muse, mutect2, varscan2
- WIZ | c.4939C>T p.R1647C (on ENST00000673675 / NM_001371589.1; = p.R552C on NM_021241.3) | Missense Mutation (SNP) | VAF 34/126 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ZFR | c.2252C>G p.T751S | Missense Mutation (SNP) | VAF 30/117 reads (26%) | SIFT tolerated (1); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- ZMYND8 | c.527C>A p.P176H (on ENST00000311275 / NM_001363741.2; = p.P196H on NM_012408.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/150 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF319 | c.1296dup p.C433Vfs*161 | Frame Shift Ins (INS) | VAF 30/144 reads (21%) | called by mutect2, pindel, varscan2
- ZNF648 | c.1056A>T p.K352N | Missense Mutation (SNP) | VAF 53/265 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- ZNF880 | c.1379G>A p.G460E | Missense Mutation (SNP) | VAF 29/109 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- APCDD1L | c.330C>T p.V110= | Silent (SNP) | VAF 44/137 reads (32%) | called by muse, mutect2, varscan2
- ARMC5 | c.333C>A p.P111= | Silent (SNP) | VAF 80/316 reads (25%) | called by muse, mutect2, varscan2
- ARSL | c.1029C>T p.S343= | Silent (SNP) | VAF 79/155 reads (51%) | called by muse, mutect2, varscan2
- ASTN2 | c.2146C>T p.L716= (on ENST00000313400 / NM_001365069.1; = p.L665= on NM_014010.5) | Silent (SNP) | VAF 22/152 reads (14%) | called by muse, mutect2, varscan2
- ATP8A2 | c.1095G>A p.T365= | Silent (SNP) | VAF 9/81 reads (11%) | catalogued as rs778237397; called by muse, mutect2, varscan2
- DOT1L | c.822T>G p.P274= | Silent (SNP) | VAF 44/216 reads (20%) | called by muse, mutect2, varscan2
- GNPAT | c.1365G>A p.L455= | Silent (SNP) | VAF 82/485 reads (17%) | called by muse, mutect2, varscan2
- GPATCH8 | c.4386C>G p.L1462= | Silent (SNP) | VAF 18/54 reads (33%) | called by muse, mutect2, varscan2
- HEATR1 | c.4554G>A p.V1518= | Silent (SNP) | VAF 31/131 reads (24%) | called by muse, mutect2, varscan2
- KCNAB3 | c.342G>A p.L114= | Silent (SNP) | VAF 54/253 reads (21%) | called by muse, mutect2, varscan2
- MED11 | c.51T>A p.I17= | Silent (SNP) | VAF 35/210 reads (17%) | called by muse, mutect2, varscan2
- MYCBPAP | c.415T>C p.L139= | Silent (SNP) | VAF 46/325 reads (14%) | catalogued as rs1194258623; called by muse, mutect2, varscan2
- POM121 | c.168C>T p.A56= | Silent (SNP) | VAF 55/187 reads (29%) | called by muse, mutect2, varscan2
- PTGES2 | c.33G>T p.L11= | Silent (SNP) | VAF 13/53 reads (25%) | called by muse, mutect2, varscan2
- REST | c.2925C>A p.P975= | Silent (SNP) | VAF 43/174 reads (25%) | called by muse, mutect2, varscan2
- RPS7 | c.579A>G p.Q193= | Silent (SNP) | VAF 7/106 reads (7%) | called by muse, mutect2
- SPHKAP | c.855A>G p.R285= | Silent (SNP) | VAF 38/150 reads (25%) | catalogued as rs761308944; called by muse, mutect2, varscan2
- TARS1 | c.676T>C p.L226= | Silent (SNP) | VAF 10/36 reads (28%) | called by muse, mutect2, varscan2
- TM2D2 | c.78G>A p.L26= | Silent (SNP) | VAF 72/343 reads (21%) | called by muse, mutect2, varscan2
- TMC4 | c.1581G>A p.Q527= (on ENST00000617472 / NM_001145303.3; = p.Q521= on NM_144686.4) | Silent (SNP) | VAF 31/111 reads (28%) | catalogued as COSV55827113; called by muse, mutect2, varscan2
- TNFAIP8L2 | c.282G>A p.L94= | Silent (SNP) | VAF 60/288 reads (21%) | called by muse, mutect2, varscan2
- TRIM31 | c.903G>A p.R301= | Silent (SNP) | VAF 16/101 reads (16%) | catalogued as COSV65059534; called by muse, mutect2, varscan2
- CCDC90B | c.-181C>G | 5'UTR (SNP) | VAF 52/227 reads (23%) | catalogued as COSV52624714; called by muse, mutect2, varscan2
- CCSER2 | c.*368T>A | 3'UTR (SNP) | VAF 70/280 reads (25%) | called by muse, mutect2, varscan2
- CEP57 | c.886-13T>G | Intron (SNP) | VAF 40/241 reads (17%) | called by muse, mutect2, varscan2
- DCAF12 | c.79-305C>A | Intron (SNP) | VAF 19/69 reads (28%) | called by muse, mutect2, varscan2
- DMTN | c.*455T>C | 3'UTR (SNP) | VAF 36/139 reads (26%) | called by muse, mutect2, varscan2
- HSPD1 | c.510+23G>T | Intron (SNP) | VAF 28/118 reads (24%) | catalogued as rs775517521; called by mutect2, varscan2
- PMS1 | c.1856+2373_1856+2375del | Intron (DEL) | VAF 7/46 reads (15%) | called by mutect2, pindel, varscan2
